MMRF case MMRF_1941 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e8c3ab17-c1ce-40ad-ae9b-7b6ef11e4501

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.1 years (21,589 days); ISS stage: II; Days to last known disease status: 950 days (2.6 years); Days to last follow up: 950 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days; Days to treatment end: 191 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 192 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -58 (ECOG 0): M Protein 2.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 34.6 mg/dL; Immunoglobulin G 38.3 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 28 g/L; Total Protein 7.3 g/dL; Glucose 4.95 mmol/L.
- Day 43 (ECOG 1): Hemoglobin 8.87 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 280 ×10⁹/L.
- Day 129 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 8.92 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 27 g/L; Total Protein 5.4 g/dL; Glucose 4.35 mmol/L.
- Day 208 (ECOG 1): Hemoglobin 7.07 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 75 ×10⁹/L.
- Day 306 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.76 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 4.45 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 30 g/L; Total Protein 5.4 g/dL; Glucose 4.84 mmol/L.
- Day 416 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.39 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.03 mmol/L; Albumin 28 g/L; Total Protein 6.1 g/dL; Glucose 4.29 mmol/L.
- Day 509 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.031 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.9 g/dL; Glucose 4.46 mmol/L.
- Day 593 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.9 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 12.7 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 5.01 mmol/L.
- Day 684 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.08 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.17 mmol/L.
- Day 775 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.2 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.03 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 859: Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.36 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 10.5 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 4.46 mmol/L.
- Day 950: M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.54 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 9.8 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -58: Weight: 99 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1941_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -58 days.
- Sample MMRF_1941_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -58 days.
